Somatic mutation profile of tumor specimen TCGA-06-6695-01A (aliquot TCGA-06-6695-01A-11D-1845-08) from TCGA case TCGA-06-6695, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 64.1 years (23,426 days).
Specimen TCGA-06-6695-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f92233b1-2987-4ab2-b5f9-b180abfbd02c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-6695-10A (Blood Derived Normal), aliquot TCGA-06-6695-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7087c9cf-3f02-4823-b7fe-f40e5ae84cad

The open-access MAF lists 55 somatic variants for this specimen: 45 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 9, Splice Region 2, Splice Site 2, Frame Shift Ins 2, In Frame Del 1, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2316_2321dup p.H773_V774dup | In Frame Ins (INS) | VAF 20/141 reads (14%) | hotspot (GDC flag); catalogued as COSV51800933, COSV51820458; called by mutect2, pindel, varscan2
- PIK3R1 | c.1138_1140del p.L380del (on ENST00000521381 / NM_181523.3; = p.L110del on NM_181504.4) | In Frame Del (DEL) | VAF 33/81 reads (41%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- A2M | c.3271A>G p.I1091V | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV59393761; called by muse, mutect2, varscan2
- ADCY5 | c.3376G>A p.G1126S | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV59194752; called by muse, mutect2, varscan2
- ANK3 | c.22T>G p.L8V | Missense Mutation (SNP) | VAF 56/83 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV55086484; called by muse, mutect2, varscan2
- ARSI | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as rs149628658; called by muse, mutect2, varscan2
- AXIN1 | c.1955G>C p.G652A | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.296); catalogued as COSV51994682; called by muse, mutect2, varscan2
- BCKDHB | c.694A>G p.K232E | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV57519625; called by muse, mutect2, varscan2
- BPIFA1 | c.666C>T p.N222= | Splice Region (SNP) | VAF 29/275 reads (11%) | catalogued as rs773494093, COSV62823863; called by muse, mutect2
- CADPS | c.3751G>A p.E1251K | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51908281; called by muse, mutect2, varscan2
- CLDN4 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.418); catalogued as rs782496885, COSV52897482; called by muse, mutect2, varscan2
- COL2A1 | c.2810C>T p.P937L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV61535310; called by muse, mutect2, varscan2
- DNAH8 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV59485987; called by muse, mutect2, varscan2
- DUSP18 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV58181653; called by muse, mutect2, varscan2
- ECHS1 | c.309G>A p.M103I | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV63907621; called by muse, mutect2, varscan2
- EPAS1 | c.2129G>A p.R710Q | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376653305; called by muse, mutect2, varscan2
- EPHA8 | c.2093G>A p.R698H | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs758537106, COSV51274707; called by muse, mutect2, varscan2
- EPPK1 | c.6622C>G p.Q2208E | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0.151); catalogued as COSV73262482; called by muse, mutect2
- ERCC4 | c.2518G>A p.E840K | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.091); catalogued as rs776625719, COSV61313950; called by muse, mutect2, varscan2
- FLT4 | c.3278C>T p.T1093M | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs770869636, COSV56125072; called by muse, mutect2, varscan2
- GFI1B | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs762113108, COSV59745830; called by muse, mutect2, varscan2
- GIMAP4 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.821); catalogued as rs753376384, COSV55431855; called by muse, mutect2, varscan2
- GKN1 | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145566771; called by muse, mutect2, varscan2
- GRIP1 | c.2039G>A p.G680E (on ENST00000359742 / NM_001379345.1; = p.G628E on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as rs778468744, COSV54024657, COSV54046478; called by muse, mutect2, varscan2
- GRIP2 | c.1810C>T p.R604C (on ENST00000619221; = p.R507C on NM_001080423.4) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs754699499, COSV56125683; called by muse, mutect2, varscan2
- IL13RA2 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 52/65 reads (80%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV54565523, COSV54567956; called by muse, mutect2, varscan2
- KBTBD4 | c.1439G>C p.R480P | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.986); catalogued as COSV58598025; called by muse, mutect2, varscan2
- KHDRBS2 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as rs374827571; called by muse, mutect2, varscan2
- KLRC1 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.945); catalogued as COSV61726199; called by muse, mutect2, varscan2
- LRRK1 | c.27dup p.S10Qfs*23 | Frame Shift Ins (INS) | VAF 31/68 reads (46%) | catalogued as rs1422179063; called by mutect2, pindel, varscan2
- LRRK2 | c.5270A>G p.N1757S | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs368762897; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP3K19 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs746658931, COSV59642858; called by muse, mutect2, varscan2
- MATR3 | c.1779-1G>A p.X593_splice | Splice Site (SNP) | VAF 18/33 reads (55%) | catalogued as COSV100735343, COSV63080772; called by muse, mutect2, varscan2
- OR5AR1 | c.844A>G p.I282V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.113); catalogued as COSV57255709; called by muse, mutect2
- PLCG2 | c.2235+2T>A p.X745_splice | Splice Site (SNP) | VAF 15/47 reads (32%) | catalogued as COSV63877708; called by muse, mutect2, varscan2
- PRR16 | c.185C>A p.T62N (on ENST00000407149 / NM_001300783.2; = p.T39N on NM_016644.2) | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65398063, COSV65407606; called by muse, mutect2, varscan2
- PRSS23 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs371463722; called by muse, mutect2, varscan2
- PZP | c.1406C>T p.T469M | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.298); catalogued as rs748511482, COSV54354857; called by muse, mutect2, varscan2
- RAPGEF4 | c.1613G>C p.C538S | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV51418692; called by muse, mutect2, varscan2
- RYR2 | c.2120C>A p.P707H | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63720237; called by muse, mutect2, varscan2
- SAMD9 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV66073077; called by muse, mutect2, varscan2
- SLC26A9 | c.951C>T p.R317= | Splice Region (SNP) | VAF 19/66 reads (29%) | catalogued as rs760498151, COSV61602677; called by muse, mutect2, varscan2
- TNFSF9 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as rs746585700, COSV55538526; called by muse, mutect2, varscan2
- WNT1 | c.506dup p.C170Lfs*6 | Frame Shift Ins (INS) | VAF 9/18 reads (50%) | catalogued as rs779969402; called by mutect2, varscan2
- YAE1 | c.392T>C p.V131A | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as COSV56233998; called by muse, mutect2, varscan2
- ADARB2 | c.1320G>A p.A440= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs777332641, COSV67224648; called by muse, mutect2, varscan2
- ANKRD11 | c.5820C>T p.S1940= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as rs368770538; called by muse, mutect2, varscan2
- C10orf71 | c.33G>A p.A11= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs370127754; called by muse, mutect2, varscan2
- CRYBG1 | c.5397A>T p.G1799= | Silent (SNP) | VAF 73/180 reads (41%) | catalogued as COSV64815238; called by muse, mutect2
- HCK | c.984C>T p.P328= | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as COSV52947914; called by muse, mutect2, varscan2
- KIR3DL1 | c.6G>A p.S2= | Silent (SNP) | VAF 63/188 reads (34%) | catalogued as rs764815860, COSV58496947; called by muse, mutect2, varscan2
- LRPAP1 | c.36G>C p.G12= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV56347733, COSV99578738; called by muse, mutect2
- PKHD1 | c.3168G>A p.S1056= | Silent (SNP) | VAF 60/165 reads (36%) | catalogued as rs771881705, COSV100581938, COSV61898011; called by muse, mutect2, varscan2
- SPDYE1 | c.645T>C p.N215= | Silent (SNP) | VAF 95/326 reads (29%) | catalogued as COSV51672877; called by muse, mutect2, varscan2
- AP003393.1 | n.896G>A | RNA (SNP) | VAF 33/91 reads (36%) | catalogued as rs545782858, COSV58229332; called by muse, mutect2, varscan2
